Somatic mutation profile of tumor specimen TCGA-QR-A70V-01A (aliquot TCGA-QR-A70V-01A-11D-A35D-08) from TCGA case TCGA-QR-A70V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 66.9 years (24,437 days).
Specimen TCGA-QR-A70V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4621fdb-b013-4b0a-9abf-68ad0de8305a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70V-10A (Blood Derived Normal), aliquot TCGA-QR-A70V-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db5a483f-f9bd-4dab-8ff8-da61c3c5e3b3

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCT6B | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1188469220; called by muse, mutect2, varscan2
- FGD6 | c.3065A>G p.Y1022C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1295287733; called by muse, mutect2, varscan2
- MRPL46 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781001525, COSV56899793; called by muse, mutect2, varscan2
- NF1 | c.5261del p.S1754Lfs*11 (on ENST00000358273 / NM_001042492.3; = p.S1733Lfs*11 on NM_000267.3) | Frame Shift Del (DEL) | VAF 14/20 reads (70%) | catalogued as COSV55986561; called by mutect2, pindel, varscan2
- PCDHB4 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as COSV52019932; called by muse, mutect2, varscan2
- PCDHB6 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV50701361, COSV50712366; called by muse, mutect2, varscan2
- BCHE | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP11B1 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DKK3 | c.382T>A p.F128I | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO21 | c.1450G>C p.E484Q (on ENST00000330622 / NM_033624.3; = p.E477Q on NM_015002.3) | Missense Mutation (SNP) | VAF 106/209 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- VPS54 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IQSEC2 | c.2094C>T p.S698= (on ENST00000642864 / NM_001111125.3; = p.S493= on NM_015075.2) | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- RNF17 | c.2199T>C p.C733= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs1451095954, COSV55043998; called by muse, mutect2, varscan2
